Gene-level copy-number profile of tumor specimen TCGA-GN-A264-06A from TCGA case TCGA-GN-A264, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 68.1 years (24,888 days).
Specimen TCGA-GN-A264-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.ffe2eb88-8e0a-4da7-a022-2978dab0aee1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GN-A264-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 821 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/12575501-7ce0-4667-8edd-23a6e9837b94

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,258; copy number 2: 16,666; copy number 3: 29,399; copy number 4: 6,831; copy number 5: 4,227; copy number 6: 1,290; copy number 8: 42; copy number 27: 45; copy number 28: 44.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GN-A264-06A-11D-A194-01): tumor purity 0.83, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 131 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–120,355,148, 44 genes, copy number 28: TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1.
- chr1:148,739,379–149,754,710, 30 genes, copy number 8: RNU6-1171P, NUDT4B, SEC22B3P, AC245389.1, PDE4DIP, RN7SKP88, RNU2-38P, AC239802.1, AC239802.2, AC239804.1, NBPF9, AC239804.2, RNVU1-24, AC245297.3, AC245297.1, AC245297.2, 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19, PPIAL4C, LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P, AC243772.3, RNU1-68P, AC243772.1.
- chr5:37,377,049–38,184,717, 12 genes, copy number 8: AC117532.1, WDR70, KCTD9P5, RNU6-1190P, RNU6-484P, GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119.
- chr12:57,723,761–57,742,157, 1 gene, copy number 27 (within-gene range 3–27): AGAP2.
- chr12:57,738,013–59,812,576, 44 genes, copy number 27: TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2, AC079905.1.

Autosomal genes at a single copy (total copy number 1): 586. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
